CPTAC case C3L-01142 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b001c1a7-7e7f-4251-adfb-19365b46f4ad

Demographics
Sex at birth: female; Race: white; Year of birth: 1975; Vital status: Alive; Country of birth: Russia.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 42.4 years (15,483 days); Year of diagnosis: 2017; Days to last known disease status: 0 days; Days to last follow up: 0 days.
   Pathology details: Greatest tumor dimension: 3.3 cm.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 0.

Other clinical attributes
- Weight: 63 kg; Height: 165 cm; BMI: 23.14.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01142-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -8 days; Initial weight: 100 mg; Time between excision and freezing: 7 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01142-21: Section location: left hemisphere frontal lobe; Percent tumor nuclei: 90; Percent necrosis: 3.
- Sample C3L-01142-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -8 days; Initial weight: 100 mg; Time between excision and freezing: 9 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01142-22: Section location: left hemisphere frontal lobe; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3L-01142-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -9 days; Method of sample procurement: Blood Draw.
